Gene-level copy-number profile of tumor specimen TCGA-CV-A6JM-01A from TCGA case TCGA-CV-A6JM, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 85.3 years (31,147 days).
Specimen TCGA-CV-A6JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.84e1a2e9-5bc0-44bc-be70-551202352f41.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-A6JM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ca15056c-75ad-401e-889f-268d706a77a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,850; copy number 2: 28,868; copy number 3: 14,436; copy number 4: 5,597; copy number 5: 3,343; copy number 6: 2,403; copy number 7: 230; copy number 8: 49; copy number 9: 10; copy number 10: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-A6JM-01A-11D-A31K-01): tumor purity 0.58, ploidy 2.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:92,613,183–92,670,131, 1 gene (within-gene range 0–2): IPPK.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,035 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,494,329–121,580,524, 5 genes, copy number 5: AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr2:169,127,109–170,655,171, 21 genes, copy number 5 (within-gene range 3–5): LRP2, BBS5, AC093899.2, KLHL41, FASTKD1, AC093899.1, PPIG, CCDC173, AC016772.1, PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1.
- chr2:171,999,943–205,620,162, 539 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr3:86,235,321–90,261,708, 37 genes, copy number 5–9: RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:148,368,384–154,024,298, 116 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr3:174,302,944–197,029,817, 465 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:54,542,325–62,275,678, 154 genes, copy number 5 (broad region; genes not listed).
- chr8:58,805,412–59,119,147, 1 gene, copy number 5 (within-gene range 4–5): TOX.
- chr8:58,991,720–85,646,325, 389 genes, copy number 5–6 (broad region; genes not listed).
- chr8:86,765,935–145,066,685, 912 genes, copy number 5–6 (broad region; genes not listed).
- chr10:42,149,310–44,310,237, 68 genes, copy number 6 (broad region; genes not listed).
- chr11:68,154,863–74,685,505, 213 genes, copy number 6–7 (broad region; genes not listed).
- chr11:74,698,231–74,699,658, 1 gene, copy number 6: AP001324.3.
- chr12:6,556,886–34,249,958, 682 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:52,482,804–79,166,885, 252 genes, copy number 5–7 (broad region; genes not listed).
- chr14:22,929,607–106,875,071, 1,929 genes, copy number 5–9 (broad region; genes not listed).
- chr15:94,168,349–101,933,350, 167 genes, copy number 5 (broad region; genes not listed).
- chr17:26,981,694–27,170,310, 7 genes, copy number 6 (within-gene range 3–6): AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2.
- chr21:23,281,736–27,492,261, 62 genes, copy number 5 (broad region; genes not listed).
- chr21:32,772,100–32,955,437, 1 gene, copy number 5 (within-gene range 3–5): C21orf62-AS1.
- chr21:32,841,496–33,071,104, 6 genes, copy number 5 (within-gene range 3–5): AP000281.1, SNORA70, AP000281.2, AP000282.1, LINC01690, OLIG2.
- chr22:46,150,521–46,357,340, 8 genes, copy number 5 (within-gene range 3–5): PPARA, FP325332.1, CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU.

Autosomal genes at a single copy (total copy number 1): 2,997. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
